Surgical pathology report (de-identified scan), TCGA case TCGA-CN-5369, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-5369-01A (Primary Tumor).

[page 1 of 6]
Pathology Report

Report Type rt
Date of Event
Sex
Authored by
Hosp/Group

PATIENT HISTORY:

Right maxillary cancer.

PRE-OP DIAGNOSIS: Right maxillary cancer.

POST-OP DIAGNOSIS: Same.

URE: None given.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT, LEVELS 2 THROUGH 4, EXCISION

FORTY-THREE LYMPH NODES, NO TUMOR PRESENT (0/43).

PARTS 2 4: LYMPH NODES, LEFT, LEVELS 2 THOROUGH 4, EXCISION

THIRTY-NINE LYMPH NODES, NO TUMOR PRESENT (0/39).

PARTS 5-9: RIGHT MAXILLA AND PALATE, RIGHT INFERIOR MAXILLARY MARGIN,
MAXILLARY BONE FRAGMENT, ADDITIONAL MAXILLA RIGHT LATERAL AND SUPERIOR MARGIN
AND ADDITIONAL LATERAL AND INFERIOR MARGIN, INFRASTRUCTURE PARTIAL
MAXILLECTOMY, AND EXCISIONS

A. POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (4.5 CM) WITH
INVASION OF MAXILLARY BONE BONE AND SALIVARY GLAND TISSUE.

B. PERINEURAL INVASION IS IDENTIFIED.

C. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.

D. ALL FINAL MARGINS OF RESECTION ARE FREE OF TUMOR.

PATHOLOGIC STAGE pT4a, N0, MX.

My si station that I have personally reviewed the submitted
material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in nine parts.

Part 1 is received unfixed, labeled with the patient's name, initials, xx and
"selective node dissection right, levels 2 through 4, stitch at 2B". The
specimen consists of a solitary 9.6 x 5.0 x 1.6 fibrofatty, focally
hemorrhagic tissue fragment with a black suture that marks level 2B. Lymph
nodes are dissected and are submitted as follows:

1A 1B representative level 2 lymph node

1C level 2, two nodes

1D level 2, four nodes

1E level 2, four nodes

1F level 2, two nodes

1G level 2b four nodes

1H level 2b three nodes

[page 2 of 6]
1I level 3, four nodes
1J level 3, four nodes
1K level 3, one node bisected
1L level 3, four nodes
1M level 4, four nodes
1N level 4, three nodes
1O level 4, three nodes.

Part 2 is received in formalin labeled with the patient's name, initials xx and "lymph node level 4". The specimen consists of a 2.5 x 1.6 x 0.5 cm focally hemorrhagic fibrofatty tissue fragment. Lymph nodes are recovered and

submitted as follows:

2A two nodes

2B one node.

Part 3 is received in formalin labeled with the patient's name, initials xx and "lymph node zone 2". The specimen consists of a 2.0 x 1.0 x 0.5 cm fibrofatty tissue fragment. The specimen is submitted as follows:

3A one node

3B two nodes.

Part 4 is received in formalin labeled with the patient's name, initials xx and "lymph node 2-4". The specimen consists of an 8.3 x 3.0 x 1.2 cm fibrofatty tissue fragment with a suture that demarcates level 2b nodes. The specimen is submitted as follows:

4A level 2, node A

4B level 2, node B

4C level 3, node A

4D level 3, node B

4E level 3, node C

4F level 4, node A

4G level 4, node B

4H loose fragment of tissue (two nodes)

4I level 2, two nodes

4K level 2, two nodes

4J level 2, four nodes

4K level 2, five nodes

4L level 2, one node

4M level 2, two nodes

4N level 3, three nodes

4O level 3, four nodes

4P level 4, two nodes

4Q level 4, three nodes

4R level 4, three nodes.

Part 5 is received in formalin labeled with the patient's name, initials xx and "maxillary mucosa". The specimen consists of a 3.0 x 4.0 x 1.0 cm fragment of mucosal lined soft tissue. A representative section is submitted in cassette 5A.

Part 6 is received unfixed for intraoperative consultation labeled with the patient's name, initials, xx and "right inferior maxillary, suture right lateral margin". The specimen consists of an oriented specimen with resection

of the maxillary sinus. This specimen is 6.6 x 5.0 x 2.2 cm with a stitch that demarcates the right lateral margin. The sinus mucosa is grossly unremarkable. On the inferior aspect of the specimen there is a 4.5 x 3.0 x 1.0 cm focally hemorrhagic friable mass that breaks through the superior cribriform plate. The tumor breaks through the bone; however, the anterior, superior and nasal septal bony margins appear to be grossly free. The lesion is 1.5 cm from the anterior margin, 1.5 cm from the medial margin and 0.6 cm

[page 3 of 6]
from the posterior margin. However, it is close, if not approximates, the lateral margin. A digital photograph is taken of the inferior aspect of the specimen with the tumor. Representative sections are submitted as follows:

6AFS tissue nearest right lateral margin
6B anterior shave
6C medial shave
6D posterior shave
6E anterior bone
6F nasal septal bony margin (decalcification)
6G superior bony margin (posterior) (decalcification)
6H 6I tumor with bone (decalcification)
6J posterior soft tissue with tumor
6K tumor in bone (decalcification)

representative sections of tumor.

is received in formalin labeled with the patient's name, initials xx and "maxillary bone fragment." The specimen consists of an aggregate of fragments of bone that is 1.0 x 1.0 x 0.3 cm. The specimen is submitted for decalcification in cassette 7A.

Part 8 is received in formalin labeled with the patient's name, initials xx and "additional margin maxilla, right lateral plus superior." The specimen consists of a 5.5 x 0.1 x 0.3 cm focally hemorrhagic mucosa-lined tissue fragment. The specimen is submitted in its entirety in 8A or 8B.

Part 9 is received in formalin labeled with the patient's name, initials xx and "additional margin lateral and inferior." The specimen consists of a 2.0 x 1.5 x 0.6 cm focally hemorrhagic, soft tissue fragment that is submitted in s tirety in cassettes 9A through 9B.

F

IVE CONSULTATION:

6AFS: RIGHT INFERIOR MAXILLARY (frozen section)
A. MALIGNANT.
B. INVASIVE SQUAMOUS CELL CARCINOMA.
C. TUMOR LESS THAN ONE HIGH POWERED FIELD FROM OFT
MARGIN, ALL OTHER MARGINS GROSSLY DISTANT. (.

C COPIC:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND MINOR SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: maxilla and hard palate, right

TUMOR SITE: Other: hard palate and maxillary sinus

TUMOR SIZE: Greatest dimension: 4.5 cm

Additional dimensions: 3.0 x 1.0 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G1

PATHOLOGIC STAGING (pTNM): pT4a

pN0

Number of regional lymph nodes examined: 82

Number of regional lymph nodes involved: 0

pMX

MARGINS: Margins uninvolved by tumor

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Absent

PERINEURAL INVASION: Present

ADDITIONAL PATHOLOGIC FINDINGS: Inflammation (type): chronic

[page 4 of 6]
Microscopic examination substantiates the above diagnosis.

PROCEDURAL NOTES:	FS	PERMANENT
level II, node A	neg	neg
level II, node B	neg	neg
level III, node A	neg	neg
level III, node B	neg	neg
level III, node C	neg	neg
level IV, node A	neg	neg
level IV, node B	neg	neg

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The [REDACTED] d its performance characteristics determined by the [REDACTED], Department of Pathology, as required by the C A [REDACTED]

[REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: [REDACTED] dissection lev

Taken: [REDACTED] Received: [REDACTED]

Stain/c

H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K
H&E x 1 L
H&E x 1 M
H&E x 1 N
H&E x 1 O

FRZ Single x 1 AFS

H&E x 1 AFS

Part 2: [REDACTED] 1 4

Taken: [REDACTED] Received: [REDACTED]

Stain/c

H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H

Part 3: [REDACTED] 1 2

Taken: [REDACTED] Received: [REDACTED]

Stain/c

H&E x 1 A
H&E x 1 B
H&E x 1 C

[page 5 of 6]
H&E x 1 D

H&E x 1 E

Part 4: 2-3-4

Taken: [REDACTED] Received: [REDACTED]

Stain/c

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

H&E x 1 J

H&E x 1 K

H&E x 1 L

H&E x 1 M

H&E x 1 N

H&E x 1 O

H&E x 1 P

H&E x 1 Q

H&E x 1 R

Part 5: y mucosa

Taken: [REDACTED] Received: [REDACTED]

Stain/c

H&E x 1 A

Part 6: maxillary

Taken: [REDACTED] Received: [REDACTED]

Stain/cn

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

H&E x 1 J

H&E x 1 K

H&E x 1 L

H&E x 1 M

Part 7: fragment

Taken: [REDACTED] Received: [REDACTED]

Stain/cn

H&E x 1 A

Part 8: gin maxilla rig perior

Taken: [REDACTED] Received: [REDACTED]

Stain/c

H&E x 1 A

H&E x 1 B

Part 9: gin lateral & i

Taken: [REDACTED] Received: [REDACTED]

Stain/cn

H&E x 1 A

H&E x 1 B

Source: NCI Genomic Data Commons file eaec4da1-d5e7-496e-abbd-268c142944b7 (TCGA-CN-5369.2D8C5F7D-27FF-400F-A67C-A947D3687171.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).